Somatic mutation profile of tumor specimen MMRF_1496_2_BM_CD138pos (aliquot MMRF_1496_2_BM_CD138pos_T1_KBS5U_L06445) from MMRF case MMRF_1496, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.9 years (14,564 days).
Specimen MMRF_1496_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44d6850d-25de-4d33-a365-abbacc2e51df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1496_3_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1496_3_PB_CD3pos_C5_KBS5U_L06506; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/024d1ad4-9117-4f0b-b5c6-e3c0ddba96f6

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, 3'UTR 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTP4A1 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV65715120; called by muse, mutect2, varscan2
- CDC42BPG | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ETAA1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- ASH2L | c.1233G>A p.R411= | Silent (SNP) | VAF 5/133 reads (4%) | called by muse, mutect2
- SPEG | c.246C>G p.L82= | Silent (SNP) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- ABCC5 | c.592-2045dup | Intron (INS) | VAF 31/176 reads (18%) | catalogued as rs748962333; called by mutect2, varscan2
- TMEM196 | c.*2400T>C | 3'UTR (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- ZFP91 | c.*1405_*1410del | 3'UTR (DEL) | VAF 25/64 reads (39%) | called by mutect2, varscan2
